MMRF case MMRF_1715 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3ff111c9-5296-4977-88ba-22c933d2e9d4

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.7 years (20,723 days); ISS stage: II; Days to last known disease status: 278 days; Days to last follow up: 278 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 126 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days; Days to treatment end: 43 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 50 days; Days to treatment end: 63 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 64 days; Days to treatment end: 64 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 159 days; Days to treatment end: 159 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 278.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 5.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.131 mg/dL; Immunoglobulin G 76.3 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 4.23 µg/mL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 71 µmol/L; Calcium 2.23 mmol/L; Albumin 30 g/L; Total Protein 11.5 g/dL; Glucose 5.9 mmol/L; C-Reactive Protein 0.1 mg/dL.
- Day 84 (ECOG 1): M Protein 6.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.028 mg/dL; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1.28 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 49 µmol/L; Calcium 2.24 mmol/L; Albumin 39.5 g/L; Total Protein 6.7 g/dL; Glucose 5.6 mmol/L.
- Day 166 (ECOG 1): M Protein 6.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.553 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.027 mg/dL; Immunoglobulin G 9.08 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 1.49 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 1.1 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.2 mmol/L; Calcium 2.44 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 7 mmol/L.
- Day 249 (ECOG 1): M Protein 4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.573 mg/dL; Immunoglobulin G 7.39 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 0.9 mmol/L; Calcium 2.35 mmol/L; Albumin 42.1 g/L; Total Protein 6.9 g/dL; Glucose 5.3 mmol/L.

Other clinical attributes
- Day -6: Weight: 63 kg; Height: 172 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1715_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1715_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
